Somatic mutation profile of tumor specimen TCGA-EE-A2A2-06A (aliquot TCGA-EE-A2A2-06A-11D-A196-08) from TCGA case TCGA-EE-A2A2, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 71.4 years (26,064 days).
Specimen TCGA-EE-A2A2-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 090c0535-dafb-498d-905e-1ba66a8564dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2A2-10A (Blood Derived Normal), aliquot TCGA-EE-A2A2-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc763b4b-a3f5-42ce-98d3-3dd777a7d84b

The open-access MAF lists 1,805 somatic variants for this specimen: 1,195 protein-altering or splice-affecting, 563 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,072, Silent 563, Nonsense Mutation 77, Splice Site 17, Intron 17, Splice Region 15, Frame Shift Del 8, 5'UTR 8, RNA 8, 5'Flank 6, 3'UTR 6, Translation Start Site 3.

Variants (750 of 1,805; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.4854G>A p.W1618* | Nonsense Mutation (SNP) | VAF 118/319 reads (37%) | catalogued as rs61752439, CM035800, COSV64672794; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs794728188, COSV57310667; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FRAS1 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as rs377046630, CM118795; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 342/1007 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 347/1010 reads (34%) | hotspot (GDC flag); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STAG2 | c.3097C>T p.R1033* | Nonsense Mutation (SNP) | VAF 40/54 reads (74%) | catalogued as rs1569520709, COSV54350149; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 229/354 reads (65%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A1CF | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs1283329728, COSV50961498; called by muse, mutect2
- AARD | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 125/347 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV65599756; called by muse, mutect2, varscan2
- AARS1 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 456/1263 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.689); catalogued as COSV99933898; called by muse, mutect2, varscan2
- ABCA7 | c.1858C>T p.L620F | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs770371503, COSV54027714; called by muse, mutect2, varscan2
- ABCA9 | c.4864G>A p.E1622K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV60623365; called by muse, mutect2, varscan2
- ABCB11 | c.2770G>A p.G924R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55588744; called by muse, mutect2, varscan2
- ABCC6 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | catalogued as rs1249307722, COSV52741921; called by muse, varscan2
- ABCD2 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58051188; called by muse, mutect2, varscan2
- ABCD3 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs148848670; called by muse, mutect2, varscan2
- ABCG4 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 287/1145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56643148; called by muse, mutect2, varscan2
- ABI3BP | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1363296475, COSV52533762; called by muse, mutect2, varscan2
- ACACB | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 216/1249 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as rs768264013, COSV58132217, COSV58140761; called by muse, mutect2, varscan2
- ACAN | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 259/768 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV100719471; called by muse, mutect2, varscan2
- ACBD5 | c.662T>A p.M221K (on ENST00000375888 / NM_001352568.1; = p.M212K on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0.03); catalogued as COSV101022488, COSV65518741; called by muse, mutect2
- ACCSL | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV66580917; called by muse, mutect2, varscan2
- ACRBP | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 321/691 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs761348118, COSV57523575; called by muse, mutect2, varscan2
- ACSM6 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV58978133; called by muse, mutect2, varscan2
- ACTN3 | c.1928A>T p.E643V | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV59748270; called by muse, mutect2, varscan2
- ADA | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 255/723 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV100866645, COSV65739954; called by muse, mutect2, varscan2
- ADAM28 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56097946; called by mutect2, varscan2
- ADAMTS16 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 55/291 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as rs368411395, COSV57001579; called by muse, mutect2, varscan2
- ADAMTS20 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs746899207, COSV67125941; called by muse, mutect2
- ADAMTS20 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 178/383 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67130026; called by muse, mutect2, varscan2
- ADAMTS9 | c.4058T>C p.V1353A | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV55779209; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1467+1G>A p.X489_splice | Splice Site (SNP) | VAF 14/51 reads (27%) | catalogued as rs761753167, COSV54444017; called by muse, mutect2
- ADCY1 | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 141/360 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52031429; called by muse, mutect2, varscan2
- ADCY5 | c.3236A>G p.N1079S | Missense Mutation (SNP) | VAF 144/416 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs758082972, COSV59196627; called by muse, mutect2, varscan2
- ADGRB3 | c.2915G>A p.G972E | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53235597; called by muse, mutect2, varscan2
- ADGRG4 | c.3761T>G p.L1254* | Nonsense Mutation (SNP) | VAF 25/33 reads (76%) | catalogued as COSV54953812; called by muse, mutect2, varscan2
- ADGRL3 | c.965C>T p.P322L (on ENST00000506720 / NM_001322402.2; = p.P254L on NM_015236.6) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV72267925, COSV72274112; called by muse, varscan2
- ADGRL4 | c.1432C>T p.L478F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1420403802, COSV66061051; called by muse, mutect2
- ADGRV1 | c.17200G>A p.E5734K | Missense Mutation (SNP) | VAF 194/401 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV67983232; called by muse, mutect2, varscan2
- ADH4 | c.1034A>T p.K345I | Missense Mutation (SNP) | VAF 159/244 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55500709; called by muse, mutect2, varscan2
- ADI1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 152/419 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs754050453, COSV59376178; called by muse, mutect2, varscan2
- ADO | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as rs780601560, COSV65677802; called by muse, varscan2
- ADPGK | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 96/278 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV61173781; called by muse, mutect2, varscan2
- AGAP3 | c.430G>A p.D144N (on ENST00000622464; = p.D180N on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 420/1198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58994220; called by muse, mutect2, varscan2
- AGFG1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59511385; called by muse, mutect2, varscan2
- AHNAK2 | c.15608C>T p.S5203F | Missense Mutation (SNP) | VAF 974/2663 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV60912899; called by muse, mutect2, varscan2
- AHNAK2 | c.12061C>T p.P4021S | Missense Mutation (SNP) | VAF 468/1471 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs199857070, COSV60912906; called by muse, mutect2, varscan2
- AHNAK2 | c.8650G>A p.G2884S | Missense Mutation (SNP) | VAF 676/1821 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.319); catalogued as COSV60912919; called by muse, mutect2, varscan2
- AHSG | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 130/311 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374953444; called by muse, mutect2, varscan2
- AIDA | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 184/360 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60663580; called by muse, mutect2, varscan2
- AK2 | c.178C>T p.P60S (on ENST00000354858; = p.P102S on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV61467329; called by muse, mutect2, varscan2
- AK5 | c.1489C>T p.L497F (on ENST00000354567 / NM_174858.3; = p.L471F on NM_012093.4) | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV60971352; called by muse, mutect2, varscan2
- AKAP8 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 170/537 reads (32%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.999); catalogued as rs1443202876, COSV54102079; called by muse, mutect2, varscan2
- AKT2 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 1011/2765 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60908175; called by muse, mutect2, varscan2
- AL121899.2 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs531290820, COSV67349536; called by muse, varscan2
- AL592490.1 | c.1916T>C p.F639S | Missense Mutation (SNP) | VAF 255/669 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69425643; called by muse, mutect2, varscan2
- ALG10B | c.731T>A p.F244Y | Missense Mutation (SNP) | VAF 138/650 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV58142945; called by muse, mutect2, varscan2
- ALPG | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 279/742 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54965236, COSV54965746; called by muse, mutect2, varscan2
- ALPK3 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 368/925 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51932317; called by muse, mutect2, varscan2
- AMACR | c.1025G>A p.R342K | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV56871106; called by muse, mutect2, varscan2
- AMBN | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.286); catalogued as COSV59825505, COSV59825826; called by muse, mutect2, varscan2
- AMZ1 | c.602-2A>G p.X201_splice | Splice Site (SNP) | VAF 107/347 reads (31%) | catalogued as COSV56686135; called by muse, mutect2, varscan2
- ANGPT1 | c.1299C>A p.D433E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99864929; called by muse, mutect2
- ANGPT1 | c.1298A>G p.D433G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99864932; called by muse, mutect2
- ANGPTL4 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 251/765 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV56844298; called by muse, mutect2, varscan2
- ANK1 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 285/867 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as COSV55879004; called by muse, mutect2, varscan2
- ANK3 | c.10716A>C p.E3572D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.003); catalogued as COSV55052977; called by muse, mutect2, varscan2
- ANK3 | c.10529C>T p.P3510L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55052988; called by muse, mutect2, varscan2
- ANK3 | c.6446C>T p.P2149L | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55053008; called by muse, mutect2, varscan2
- ANK3 | c.3413C>T p.S1138F (on ENST00000280772 / NM_001320874.2; = p.S272F on NM_001149.3) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55053021; called by muse, mutect2, varscan2
- ANK3 | c.2858G>A p.R953K (on ENST00000280772 / NM_001320874.2; = p.R87K on NM_001149.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1326736953, COSV55053043; called by muse, mutect2
- ANKRD30A | c.1156G>A p.E386K (on ENST00000611781; = p.E330K on NM_052997.2) | Missense Mutation (SNP) | VAF 66/213 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.292); catalogued as COSV64608348; called by muse, mutect2, varscan2
- ANXA11 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 212/567 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs778270793, COSV55415748; called by muse, mutect2, varscan2
- AOC1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 206/583 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV62868099; called by muse, mutect2, varscan2
- AOPEP | c.2176C>T p.P726S (on ENST00000375315 / NM_001193329.1; = p.P627S on NM_032823.5) | Missense Mutation (SNP) | VAF 129/236 reads (55%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV52988814; called by muse, mutect2, varscan2
- AP1G1 | c.2117C>T p.S706F | Missense Mutation (SNP) | VAF 198/534 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV55488070; called by muse, mutect2, varscan2
- AP3B2 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 139/538 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99917175; called by muse, mutect2, varscan2
- AP4E1 | c.1832G>A p.R611K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1340418087, COSV99957356; called by muse, mutect2, varscan2
- AP4E1 | c.1833G>T p.R611S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99957357; called by muse, mutect2, varscan2
- AP4E1 | c.2369C>T p.S790F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.359); catalogued as COSV55916358; called by muse, mutect2
- APBB1 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 250/565 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as rs200437076, COSV54974560; called by muse, mutect2, varscan2
- APOF | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 353/830 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV58475009; called by muse, mutect2, varscan2
- AQP10 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 665/1276 reads (52%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.995); catalogued as COSV61474787; called by muse, mutect2, varscan2
- ARAP1 | c.2903C>T p.S968L (on ENST00000393609 / NM_001040118.2; = p.S723L on NM_015242.4) | Missense Mutation (SNP) | VAF 1049/2200 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs757748235, COSV61990683; called by muse, mutect2, varscan2
- ARHGAP11A | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1372690606, COSV100276961, COSV55705946; called by muse, mutect2, varscan2
- ARHGAP22 | c.2045C>T p.S682L | Missense Mutation (SNP) | VAF 196/716 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs375289109; called by muse, mutect2, varscan2
- ARHGAP31 | c.2945G>A p.R982K | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV51791607; called by muse, mutect2, varscan2
- ARHGEF19 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 89/263 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs142369162; called by muse, varscan2
- ARID1A | c.2393C>T p.P798L | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs140683722; called by muse, mutect2, varscan2
- ARID1B | c.4204G>A p.D1402N | Missense Mutation (SNP) | VAF 105/184 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV99273367; called by muse, mutect2, varscan2
- ARID2 | c.4150C>T p.H1384Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.42); PolyPhen probably damaging (0.986); catalogued as COSV57601509; called by muse, mutect2, varscan2
- ARID3C | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 397/1045 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV66697781; called by muse, mutect2, varscan2
- ARMC4 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as rs765376476, COSV59461397; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARMH3 | c.1192C>T p.L398F | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV64234311; called by muse, mutect2, varscan2
- ARMT1 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 97/148 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100939868; called by muse, mutect2, varscan2
- ARMT1 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 93/143 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs778214484, COSV66178794; called by muse, mutect2, varscan2
- ARRB2 | c.756T>A p.C252* | Nonsense Mutation (SNP) | VAF 471/685 reads (69%) | catalogued as COSV99347342; called by muse, mutect2, varscan2
- ARRB2 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 463/671 reads (69%) | SIFT tolerated (0.6); PolyPhen benign (0.049); catalogued as COSV99347344; called by muse, mutect2, varscan2
- ASMT | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 218/362 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV67109769; called by muse, mutect2, varscan2
- ASPM | c.7082C>T p.S2361F | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54128225; called by muse, varscan2
- ASXL3 | c.2783G>A p.G928E | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as COSV52456596; called by muse, mutect2, varscan2
- ATAD2 | c.345dup p.K116* | Frame Shift Ins (INS) | VAF 49/179 reads (27%) | catalogued as COSV54881227, COSV99784572; called by mutect2, pindel, varscan2
- ATG14 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55956168; called by muse, mutect2, varscan2
- ATG2A | c.4117C>T p.P1373S | Missense Mutation (SNP) | VAF 222/540 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.1); catalogued as COSV101034957; called by muse, mutect2, varscan2
- ATP11C | c.1780-2A>T p.X594_splice | Splice Site (SNP) | VAF 113/140 reads (81%) | catalogued as COSV59562233; called by muse, mutect2, varscan2
- ATP13A5 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV60868223; called by muse, mutect2, varscan2
- ATP2C2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV52294579; called by muse, mutect2, varscan2
- ATP2C2 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 93/305 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs267604666, COSV52294600; called by muse, mutect2, varscan2
- ATP6V1G3 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as rs776856347, COSV55278194, COSV99811103; called by muse, varscan2
- ATP7B | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs775352622, COSV54437372; called by muse, mutect2, varscan2
- ATR | c.7066C>T p.R2356C | Missense Mutation (SNP) | VAF 160/461 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs755264430, COSV63385618; called by muse, mutect2, varscan2
- AXIN1 | c.1946C>T p.T649I | Missense Mutation (SNP) | VAF 673/1765 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV51986041; called by muse, mutect2, varscan2
- AXL | c.2401G>A p.E801K (on ENST00000301178 / NM_021913.5; = p.E792K on NM_001699.6) | Missense Mutation (SNP) | VAF 177/522 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs745319533, COSV56566991; called by muse, mutect2, varscan2
- BANK1 | c.1424T>C p.V475A | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs749627068, COSV59841471; called by muse, varscan2
- BAP1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 900/2411 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56233081, COSV56238059; called by muse, mutect2, varscan2
- BBS10 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 259/572 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV101283351, COSV67913150; called by muse, mutect2, varscan2
- BCL2L11 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 200/605 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100427565; called by muse, mutect2, varscan2
- BCL2L11 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 202/600 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100427569; called by muse, mutect2, varscan2
- BCL2L12 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 698/2116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55862879; called by muse, mutect2, varscan2
- BCLAF1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs57380832, COSV62141540; called by muse, mutect2, varscan2
- BCORL1 | c.5044G>A p.G1682S | Missense Mutation (SNP) | VAF 274/351 reads (78%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV54394119; called by muse, varscan2
- BMP5 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63702532, COSV63706127; called by muse, mutect2, varscan2
- BMPER | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 382/910 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1396613035, COSV51815955; called by muse, mutect2, varscan2
- BMPR1B | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52776368; called by muse, mutect2, varscan2
- BNIP5 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as rs149916620; called by muse, mutect2, varscan2
- BPIFA1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 113/333 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV62824225; called by muse, mutect2, varscan2
- BPNT2 | c.593T>A p.V198E | Missense Mutation (SNP) | VAF 142/415 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52907135; called by muse, mutect2, varscan2
- BPTF | c.5321C>T p.S1774F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV58835333, COSV58845124; called by muse, mutect2, varscan2
- BRICD5 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.158); catalogued as COSV57027572; called by muse, varscan2
- BRINP2 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs370977427; called by muse, mutect2, varscan2
- BRPF3 | c.3344C>T p.P1115L | Missense Mutation (SNP) | VAF 74/271 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1437335054, COSV60206871; called by muse, mutect2, varscan2
- BRSK1 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 158/447 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV58665823; called by muse, mutect2, varscan2
- BTAF1 | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV56432393; called by muse, mutect2, varscan2
- BYSL | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 127/345 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV57828282; called by muse, mutect2, varscan2
- C10orf62 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 140/451 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as COSV101035345; called by muse, mutect2, varscan2
- C10orf71 | c.1166A>T p.K389I | Missense Mutation (SNP) | VAF 240/634 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV60506629; called by muse, mutect2, varscan2
- C12orf40 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV61131200; called by muse, mutect2, varscan2
- C14orf39 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.124); catalogued as COSV58781122; called by muse, mutect2, varscan2
- C2orf78 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 181/437 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV68517211; called by muse, mutect2, varscan2
- C3 | c.2441-1G>A p.X814_splice | Splice Site (SNP) | VAF 42/115 reads (37%) | catalogued as COSV55571481, COSV99837321; called by muse, mutect2, varscan2
- C6orf15 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 108/262 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV52537412; called by muse, mutect2, varscan2
- C8A | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV63483658; called by muse, mutect2, varscan2
- C8B | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV100980967; called by muse, varscan2
- CACNA2D3 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.433); catalogued as COSV55530055; called by muse, mutect2, varscan2
- CACNG1 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs762655686, COSV56827174; called by muse, mutect2, varscan2
- CACNG1 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1267001431, COSV99871856; called by muse, mutect2
- CACNG4 | c.331C>G p.P111A | Missense Mutation (SNP) | VAF 325/1087 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50924679; called by muse, mutect2, varscan2
- CAD | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 199/558 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV53025636; called by muse, mutect2, varscan2
- CADM2 | c.718G>A p.E240K (on ENST00000407528 / NM_001167674.2; = p.E242K on NM_153184.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67358651; called by muse, mutect2, varscan2
- CALB1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 445/1211 reads (37%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.987); catalogued as rs774827262, COSV55366486; called by muse, mutect2, varscan2
- CALN1 | c.331C>T p.R111C (on ENST00000329008 / NM_001017440.3; = p.R153C on NM_031468.4) | Missense Mutation (SNP) | VAF 164/422 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1473772101, COSV61127841, COSV61144822; called by muse, mutect2, varscan2
- CAMTA2 | c.1601C>T p.T534I | Missense Mutation (SNP) | VAF 419/684 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61833286, COSV61834345; called by muse, mutect2, varscan2
- CAND2 | c.2815G>A p.A939T (on ENST00000456430 / NM_001162499.2; = p.A846T on NM_012298.3) | Missense Mutation (SNP) | VAF 462/1168 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV55988987; called by muse, mutect2, varscan2
- CAPN13 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs368104197; called by muse, mutect2, varscan2
- CAPRIN1 | c.437T>G p.L146* | Nonsense Mutation (SNP) | VAF 74/131 reads (56%) | catalogued as COSV58219403; called by muse, mutect2, varscan2
- CASKIN1 | c.4270G>C p.D1424H | Missense Mutation (SNP) | VAF 94/229 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58213870; called by muse, varscan2
- CASKIN1 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 103/307 reads (34%) | catalogued as COSV58213873; called by muse, mutect2, varscan2
- CASKIN1 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 344/857 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV58871769; called by muse, mutect2, varscan2
- CASP9 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV61601297; called by muse, mutect2, varscan2
- CASR | c.1474C>T p.P492S (on ENST00000490131; = p.P569S on NM_000388.4) | Missense Mutation (SNP) | VAF 327/908 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1271168512, COSV56136523; called by muse, mutect2, varscan2
- CASR | c.2507C>T p.S836F (on ENST00000490131; = p.S913F on NM_000388.4) | Missense Mutation (SNP) | VAF 94/275 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs751273631, COSV99949587; called by muse, mutect2, varscan2
- CATSPERD | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV58464284; called by muse, mutect2, varscan2
- CBS | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 312/490 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61442438; called by muse, mutect2, varscan2
- CCDC185 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 207/366 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0.054); catalogued as rs1198048371, COSV64820661; called by muse, mutect2, varscan2
- CCDC50 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as COSV66667695; called by muse, mutect2, varscan2
- CCDC74A | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 136/1265 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as COSV54606176; called by mutect2, varscan2
- CCDC74B | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 247/879 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as rs761686902, COSV60101649; called by muse, mutect2, varscan2
- CCKBR | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 210/436 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV58100458; called by muse, mutect2, varscan2
- CCNB3 | c.3973G>A p.E1325K | Missense Mutation (SNP) | VAF 81/102 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV52072323; called by muse, mutect2, varscan2
- CCNF | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 263/690 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53539379; called by muse, mutect2, varscan2
- CCNT1 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 249/547 reads (46%) | catalogued as COSV56063950; called by muse, mutect2, varscan2
- CCR3 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867615905, COSV62462640; called by muse, mutect2, varscan2
- CCR3 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV62462650; called by muse, mutect2, varscan2
- CCR4 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 184/408 reads (45%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.745); catalogued as COSV58381995; called by muse, mutect2, varscan2
- CCT8L2 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 197/576 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV63462147, COSV63462222; called by muse, mutect2, varscan2
- CD163 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.26); catalogued as COSV63131450, COSV63132028; called by muse, mutect2, varscan2
- CD163L1 | c.2540G>A p.G847E | Missense Mutation (SNP) | VAF 83/180 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV58010794, COSV58025502; called by muse, mutect2, varscan2
- CD163L1 | c.2539G>A p.G847R | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100550845; called by muse, mutect2, varscan2
- CD300LD | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 126/364 reads (35%) | catalogued as rs747063220, COSV60083596, COSV60083761; called by muse, mutect2, varscan2
- CD86 | c.950C>T p.S317L (on ENST00000330540 / NM_175862.5; = p.S311L on NM_006889.4) | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141281931, COSV100053925; called by muse, mutect2, varscan2
- CDC27 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV50365032; called by muse, mutect2, varscan2
- CDH22 | c.1589G>A p.G530D | Missense Mutation (SNP) | VAF 134/324 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.139); catalogued as COSV64837182; called by muse, mutect2, varscan2
- CDH4 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 170/430 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375893301; called by muse, mutect2, varscan2
- CDH6 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54067902; called by muse, mutect2, varscan2
- CDH8 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as rs1225853270, COSV54860810; called by muse, mutect2, varscan2
- CDK14 | c.1282G>A p.E428K (on ENST00000380050 / NM_001287135.2; = p.E410K on NM_012395.3) | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV56031455, COSV99726069; called by muse, mutect2, varscan2
- CDK17 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779161958, COSV54128207; called by muse, mutect2, varscan2
- CDR2L | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV61500915; called by muse, mutect2, varscan2
- CEACAM5 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 129/352 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV55751716; called by muse, mutect2, varscan2
- CECR2 | c.3544G>A p.G1182S (on ENST00000342247 / NM_001290047.2; = p.G998S on NM_001290046.1) | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1039039190, COSV52839491; called by muse, mutect2, varscan2
- CELF4 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 119/263 reads (45%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.914); catalogued as COSV100611282, COSV58451355; called by muse, mutect2, varscan2
- CENPC | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.749); catalogued as COSV56622373; called by muse, mutect2, varscan2
- CER1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV66603090; called by muse, mutect2, varscan2
- CFAP43 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV99531139; called by muse, mutect2, varscan2
- CFAP46 | c.7501+1G>A p.X2501_splice | Splice Site (SNP) | VAF 273/702 reads (39%) | catalogued as COSV54151118; called by muse, mutect2, varscan2
- CFAP53 | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 163/382 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as rs756279535, COSV68351758; called by muse, mutect2, varscan2
- CFAP58 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 99/236 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); catalogued as rs1258282490, COSV57211343, COSV57211825; called by muse, mutect2, varscan2
- CFAP61 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 117/331 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as COSV55625912; called by muse, mutect2, varscan2
- CFAP65 | c.4222C>T p.H1408Y | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100446095; called by muse, mutect2, varscan2
- CFAP65 | c.3846G>A p.L1282= | Splice Region (SNP) | VAF 60/157 reads (38%) | catalogued as COSV58559812; called by muse, mutect2, varscan2
- CFAP70 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV60282542; called by muse, mutect2, varscan2
- CFAP74 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 169/403 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV54566667; called by muse, mutect2, varscan2
- CFAP77 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 173/292 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV58009404; called by muse, mutect2, varscan2
- CFP | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 134/157 reads (85%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs1465013743, COSV55950060; called by muse, varscan2
- CHD6 | c.3557G>A p.G1186E | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV58556060; called by muse, mutect2, varscan2
- CHD7 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 581/1348 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as COSV71108676; called by muse, mutect2, varscan2
- CHL1 | c.970C>T p.H324Y (on ENST00000397491 / NM_001253387.1; = p.H340Y on NM_006614.4) | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as rs750669454, COSV56590942; called by muse, mutect2, varscan2
- CHL1 | c.3508G>A p.G1170R (on ENST00000397491 / NM_001253387.1; = p.G1186R on NM_006614.4) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1166700741, COSV56590955; called by muse, mutect2, varscan2
- CHODL | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 52/82 reads (63%) | catalogued as rs561040335, COSV54731611; called by muse, mutect2, varscan2
- CHRD | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 278/760 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV52607129; called by muse, mutect2, varscan2
- CHRNA6 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 85/212 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV52379194; called by muse, varscan2
- CHST6 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 297/731 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144301922, COSV60000216; called by muse, mutect2, varscan2
- CIITA | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 277/739 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs747159521, COSV60856227; called by muse, mutect2, varscan2
- CLBA1 | c.521A>T p.E174V | Missense Mutation (SNP) | VAF 233/603 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV66347959; called by muse, mutect2, varscan2
- CLCA3P | n.464G>A | Splice Region (SNP) | VAF 43/122 reads (35%) | catalogued as rs373518265; called by muse, mutect2, varscan2
- CLCC1 | c.1417G>A p.E473K (on ENST00000356970 / NM_001377464.1; = p.E423K on NM_015127.5) | Missense Mutation (SNP) | VAF 728/1830 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.602); catalogued as rs762746925, COSV51442028; called by muse, varscan2
- CLCN1 | c.2508G>A p.K836= | Splice Region (SNP) | VAF 170/472 reads (36%) | catalogued as rs1160950660, COSV58367570, COSV58369066; called by muse, varscan2
- CLDN11 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 134/367 reads (37%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.648); catalogued as COSV50355319; called by muse, mutect2, varscan2
- CLEC2B | c.151A>G p.K51E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57309336; called by muse, mutect2, varscan2
- CLPS | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 191/724 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as rs1181803210, COSV52566142; called by muse, mutect2, varscan2
- CLRN1 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55805379; called by muse, mutect2, varscan2
- CNOT6L | c.713T>C p.L238P (on ENST00000504123 / NM_001286790.2; = p.L233P on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53698711; called by muse, mutect2, varscan2
- CNPY2 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 291/1212 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as COSV56263840, COSV56264205; called by muse, mutect2, varscan2
- CNST | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 312/1280 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.301); catalogued as COSV63620233; called by muse, mutect2, varscan2
- CNTN1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61638643; called by muse, mutect2, varscan2
- CNTN5 | c.2723G>A p.G908E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54282866; called by muse, mutect2, varscan2
- CNTNAP1 | c.2027C>T p.S676F | Missense Mutation (SNP) | VAF 480/1359 reads (35%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.634); catalogued as COSV52849330; called by muse, mutect2, varscan2
- CNTNAP2 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV62167486; called by muse, mutect2, varscan2
- CNTNAP4 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100273817; called by muse, mutect2
- CNTNAP4 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 109/277 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV56674972; called by muse, mutect2, varscan2
- COL14A1 | c.1916G>A p.S639N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV52851983; called by muse, mutect2, varscan2
- COL18A1 | c.3435C>T p.G1145= (on ENST00000359759 / NM_130444.3; = p.G910= on NM_030582.4) | Splice Region (SNP) | VAF 390/594 reads (66%) | catalogued as rs761372342, COSV100644977, COSV60588055; called by muse, mutect2, varscan2
- COL22A1 | c.2981C>T p.S994L | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57332502; called by muse, mutect2, varscan2
- COL26A1 | c.476C>T p.P159L (on ENST00000313669 / NM_001278563.3; = p.P157L on NM_133457.4) | Missense Mutation (SNP) | VAF 92/287 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV58123215; called by muse, mutect2, varscan2
- COL27A1 | c.5182G>A p.G1728R | Missense Mutation (SNP) | VAF 141/217 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100621420; called by muse, mutect2, varscan2
- COL27A1 | c.5183G>T p.G1728V | Missense Mutation (SNP) | VAF 138/216 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100621421; called by muse, mutect2, varscan2
- COL4A2 | c.3779G>A p.G1260E | Missense Mutation (SNP) | VAF 206/568 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64627164; called by muse, mutect2, varscan2
- COL5A1 | c.4804G>C p.V1602L | Missense Mutation (SNP) | VAF 207/338 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65667880; called by muse, mutect2, varscan2
- COL5A3 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 199/425 reads (47%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); catalogued as COSV53409213; called by muse, mutect2, varscan2
- COL7A1 | c.6241C>T p.P2081S | Missense Mutation (SNP) | VAF 319/754 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs772966335, COSV60394069; called by muse, mutect2, varscan2
- COL8A1 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.097); catalogued as COSV53732499, COSV53740065; called by muse, mutect2, varscan2
- COLEC12 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1275199748, COSV68369975; called by muse, mutect2, varscan2
- COMT | c.578G>A p.W193* | Nonsense Mutation (SNP) | VAF 258/674 reads (38%) | catalogued as COSV52889609; called by muse, mutect2, varscan2
- CORO2B | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 114/266 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV55952049; called by muse, mutect2, varscan2
- CPEB2 | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV52589714; called by muse, varscan2
- CPNE4 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.146); catalogued as COSV70193103; called by muse, mutect2, varscan2
- CPXM1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 201/464 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); catalogued as COSV66045100, COSV66045242; called by muse, mutect2, varscan2
- CR1L | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 284/681 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV54323619; called by muse, mutect2, varscan2
- CR2 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 101/184 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV65507137; called by muse, mutect2, varscan2
- CRACR2A | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 84/187 reads (45%) | catalogued as rs1461570785, COSV52911898; called by muse, mutect2, varscan2
- CROCC | c.2948C>T p.S983F | Missense Mutation (SNP) | VAF 120/334 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs1231600904, COSV65011410; called by muse, mutect2
- CSMD2 | c.8249G>A p.G2750D | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99597256; called by muse, varscan2
- CSMD2 | c.8248G>A p.G2750S | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs144107939; called by muse, varscan2
- CSMD2 | c.8155C>T p.P2719S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV53890177, COSV53891470, COSV53901887; called by muse, varscan2
- CSMD3 | c.11084G>A p.R3695Q (on ENST00000297405 / NM_001363185.1; = p.R3526Q on NM_052900.3) | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs747508555, COSV52118172, COSV52153817, COSV99828442; called by muse, mutect2, varscan2
- CTNNA3 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV65571237; called by muse, mutect2, varscan2
- CUBN | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64713395, COSV64727389; called by muse, mutect2, varscan2
- CYFIP2 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 146/240 reads (61%) | catalogued as COSV59034421; called by muse, varscan2
- CYLC2 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); catalogued as COSV66337152; called by muse, mutect2, varscan2
- CYP11B1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 250/625 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs762347776, COSV52825046; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CYP11B2 | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 215/666 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1021038658, COSV59995267, COSV59995534; called by muse, mutect2, varscan2
- CYP1A1 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 221/642 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.4); catalogued as COSV65696947; called by muse, mutect2, varscan2
- CYP2A6 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 253/743 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV56534807; called by muse, mutect2, varscan2
- CYP2A7 | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 164/578 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.228); catalogued as rs780712942, COSV99394633; called by muse, mutect2
- CYP2B6 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV57843317; called by muse, mutect2, varscan2
- CYP4F8 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 166/523 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs768693886, COSV57853310; called by muse, mutect2, varscan2
- DACH1 | c.1672G>A p.D558N (on ENST00000619232 / NM_001366712.1; = p.D506N on NM_080759.6) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV57496154; called by muse, mutect2, varscan2
- DAG1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.452); catalogued as COSV100445282; called by muse, mutect2, varscan2
- DCAF8 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 115/204 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.528); catalogued as rs186360966; called by muse, mutect2, varscan2
- DCANP1 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 115/165 reads (70%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.093); catalogued as COSV72345763, COSV72345947; called by muse, mutect2, varscan2
- DCDC2 | c.662G>A p.S221N | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.102); catalogued as COSV101016298, COSV65831541; called by muse, mutect2, varscan2
- DCLRE1B | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 444/1093 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.092); catalogued as COSV65812559; called by muse, mutect2, varscan2
- DDX17 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 171/431 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549944631, COSV53251920; called by muse, mutect2, varscan2
- DDX51 | c.1855C>T p.R619* | Nonsense Mutation (SNP) | VAF 256/549 reads (47%) | catalogued as rs1018578088, COSV57957887; called by muse, mutect2, varscan2
- DDX60 | c.2869C>T p.R957C | Missense Mutation (SNP) | VAF 60/77 reads (78%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs752328810, COSV67095709; called by muse, mutect2, varscan2
- DEAF1 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 159/332 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs193920740, COSV100102250, COSV58606680; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DENND3 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 269/798 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52802065; called by muse, mutect2, varscan2
- DEPDC1 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 123/342 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63958033; called by muse, mutect2, varscan2
- DEPDC5 | c.3378G>A p.M1126I (on ENST00000400246; = p.M1195I on NM_014662.5) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.057); catalogued as rs756692170, COSV56695203; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DGKH | c.2054C>T p.S685F | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV54930534; called by muse, mutect2
- DGKH | c.2056C>T p.P686S | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54930550; called by muse, mutect2
- DHX57 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 228/758 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV54884231; called by muse, mutect2, varscan2
- DIP2C | c.2794+2T>C p.X932_splice | Splice Site (SNP) | VAF 141/425 reads (33%) | catalogued as COSV55153888; called by muse, mutect2, varscan2
- DIPK1C | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 296/805 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59724539; called by muse, mutect2, varscan2
- DLC1 | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 72/191 reads (38%) | catalogued as rs866224883, COSV52299250, COSV99360856; called by muse, mutect2, varscan2
- DLG5 | c.2585G>A p.G862E | Missense Mutation (SNP) | VAF 273/638 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV64947581; called by muse, mutect2, varscan2
- DLK1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 200/578 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as rs1307123936, COSV57991244; called by muse, mutect2, varscan2
- DLL1 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 230/348 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV64537201; called by muse, mutect2, varscan2
- DMBT1 | c.2966C>T p.S989F (on ENST00000338354 / NM_001377530.1; = p.S490F on NM_004406.3) | Missense Mutation (SNP) | VAF 385/1165 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV57540754; called by muse, mutect2, varscan2
- DMBT1 | c.4954G>A p.E1652K (on ENST00000338354 / NM_001377530.1; = p.E895K on NM_004406.3) | Missense Mutation (SNP) | VAF 345/925 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57540767; called by muse, mutect2, varscan2
- DMBT1 | c.5191G>A p.E1731K (on ENST00000338354 / NM_001377530.1; = p.E974K on NM_004406.3) | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV57540784; called by muse, mutect2, varscan2
- DMBT1 | c.6472C>T p.P2158S (on ENST00000338354 / NM_001377530.1; = p.P1401S on NM_004406.3) | Missense Mutation (SNP) | VAF 97/344 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as rs764696806, COSV57540802; called by muse, mutect2, varscan2
- DNAAF1 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 121/265 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV58985811; called by muse, mutect2
- DNAH11 | c.5500C>T p.R1834C | Missense Mutation (SNP) | VAF 109/318 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs180897552, CM140771, COSV60944662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH11 | c.8762G>A p.S2921N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.373); catalogued as COSV60951554; called by muse, varscan2
- DNAH17 | c.3674C>T p.S1225F | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.188); catalogued as COSV67752352; called by muse, mutect2, varscan2
- DNAH3 | c.8137G>A p.E2713K | Missense Mutation (SNP) | VAF 234/602 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.825); catalogued as COSV54515634; called by muse, mutect2, varscan2
- DNAH3 | c.5439G>T p.K1813N | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54515650; called by muse, mutect2, varscan2
- DNAH5 | c.10802C>T p.P3601L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54218063; called by muse, mutect2, varscan2
- DNAH5 | c.9706G>A p.D3236N | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs374206128, COSV99451113; called by muse, varscan2
- DNAH5 | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV54218086, COSV99448639; called by muse, mutect2, varscan2
- DNAH7 | c.4828G>A p.E1610K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs753441938, COSV56759996; called by muse, varscan2
- DNAH8 | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.163); catalogued as COSV59438309; called by muse, mutect2, varscan2
- DNAH8 | c.4034C>T p.S1345L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.439); catalogued as COSV59438362; called by muse, mutect2, varscan2
- DNAH8 | c.9640T>G p.W3214G | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1277813623, COSV59438385; called by muse, mutect2, varscan2
- DNAH9 | c.3269G>A p.R1090Q | Missense Mutation (SNP) | VAF 99/193 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as rs948668451, COSV52344965; called by muse, mutect2, varscan2
- DNAJB9 | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 195/558 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0.138); catalogued as rs1301632803, COSV50812052, COSV50812442; called by muse, mutect2, varscan2
- DNTTIP2 | c.1910G>C p.R637P | Missense Mutation (SNP) | VAF 146/427 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756513922, COSV63283920; called by muse, mutect2, varscan2
- DOC2A | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 285/819 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV58751098; called by muse, mutect2, varscan2
- DOCK3 | c.5536C>T p.P1846S | Missense Mutation (SNP) | VAF 170/417 reads (41%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.007); catalogued as COSV56515128; called by muse, mutect2, varscan2
- DOCK6 | c.3385T>A p.F1129I | Missense Mutation (SNP) | VAF 100/299 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as COSV53913438; called by muse, mutect2, varscan2
- DPP10 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.67); catalogued as rs1271674082, COSV59679853; called by muse, mutect2, varscan2
- DPYD | c.1732C>T p.L578F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286575905, COSV64589756, COSV64594991; called by muse, varscan2
- DRD5 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 313/501 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1243369550, COSV58577598; called by muse, mutect2, varscan2
- DROSHA | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100757873; called by muse, mutect2, varscan2
- DROSHA | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV60783646; called by muse, mutect2, varscan2
- DSC2 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs867968395, COSV51863446; called by muse, mutect2, varscan2
- DSC3 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772619208, COSV64572594; called by muse, mutect2, varscan2
- DSCAM | c.3728C>T p.S1243L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.71); PolyPhen benign (0.062); catalogued as rs762143046, COSV68021459; called by muse, mutect2, varscan2
- DSG4 | c.2021G>A p.G674E | Missense Mutation (SNP) | VAF 302/850 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.521); catalogued as COSV57390502; called by muse, mutect2, varscan2
- DSP | c.5615C>T p.S1872F | Missense Mutation (SNP) | VAF 169/469 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.395); catalogued as COSV65791105; called by muse, mutect2, varscan2
- DTX1 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 446/886 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746199861, COSV57496820; called by muse, varscan2
- DTX1 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 87/383 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV55655251; called by muse, mutect2, varscan2
- DUOX2 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 420/1346 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV66531548; called by muse, mutect2, varscan2
- DUSP15 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 110/346 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs377341994; called by muse, mutect2, varscan2
- DUSP5 | c.589T>G p.C197G | Missense Mutation (SNP) | VAF 523/1506 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.466); catalogued as COSV63645595; called by muse, mutect2, varscan2
- DYNC2H1 | c.3977C>T p.S1326L | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV62091801; called by muse, mutect2, varscan2
- DYNLRB2 | c.107A>G p.N36S | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs374532127, COSV58416345; called by muse, mutect2, varscan2
- DYRK4 | c.235A>C p.K79Q | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV50538633; called by muse, mutect2, varscan2
- DYTN | c.1474C>G p.P492A | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV71751866; called by muse, mutect2, varscan2
- ECI1 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV100067110; called by muse, mutect2, varscan2
- EDAR | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 161/440 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51500538; called by muse, mutect2, varscan2
- EDDM3B | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs534719745, COSV58746893; called by muse, mutect2, varscan2
- EFCAB13 | c.2753G>A p.R918K | Missense Mutation (SNP) | VAF 87/231 reads (38%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.005); catalogued as COSV58947629; called by muse, mutect2, varscan2
- EFL1 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1317904588, COSV51604669, COSV99188117; called by muse, mutect2, varscan2
- EGFLAM | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59295524; called by muse, mutect2, varscan2
- EIF2AK3 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 184/431 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.214); catalogued as COSV57546601; called by muse, mutect2, varscan2
- EIF2D | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 67/289 reads (23%) | catalogued as COSV55113236; called by muse, mutect2, varscan2
- EIF3E | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV55202422; called by muse, mutect2, varscan2
- ELF2 | c.685A>G p.K229E (on ENST00000379550 / NM_001331036.2; = p.K169E on NM_006874.4) | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55492615, COSV55493103; called by muse, mutect2, varscan2
- EMILIN2 | c.1639C>T p.Q547* | Nonsense Mutation (SNP) | VAF 183/525 reads (35%) | catalogued as COSV54422703, COSV99598147; called by muse, mutect2, varscan2
- ENC1 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 86/544 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs773788171, COSV56629300; called by muse, mutect2, varscan2
- EPN1 | c.1600C>T p.R534C (on ENST00000270460 / NM_001321263.1; = p.R508C on NM_013333.3) | Missense Mutation (SNP) | VAF 136/317 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs368790286; called by muse, mutect2, varscan2
- EPPK1 | c.2024C>T p.P675L | Missense Mutation (SNP) | VAF 139/369 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1554661075, COSV73261056; called by muse, mutect2, varscan2
- EPS8 | c.184A>T p.I62L | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV55529628; called by muse, varscan2
- ERC2 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV55614778; called by muse, mutect2, varscan2
- ERICH3 | c.2515G>A p.A839T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as rs200840954, COSV58604339; called by muse, varscan2
- ERICH3 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV58604352; called by muse, mutect2, varscan2
- ERN1 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.201); catalogued as rs899566036, COSV70501471; called by muse, mutect2, varscan2
- ERN2 | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 561/1417 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56832886; called by muse, mutect2, varscan2
- ESPL1 | c.1369+1G>A p.X457_splice | Splice Site (SNP) | VAF 134/551 reads (24%) | catalogued as COSV57758757; called by muse, mutect2, varscan2
- ESR2 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 176/544 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV50829830; called by muse, varscan2
- ETV1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54136760, COSV54140570; called by muse, mutect2, varscan2
- EVA1C | c.848A>C p.D283A | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs773681344, COSV55823693; called by muse, mutect2, varscan2
- EXO5 | c.395T>G p.V132G | Missense Mutation (SNP) | VAF 162/477 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV56415576; called by muse, mutect2, varscan2
- EXOC6 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 111/341 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53322654; called by muse, varscan2
- F13B | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.982); catalogued as COSV66372091, COSV66373336; called by muse, mutect2, varscan2
- F5 | c.6492G>A p.W2164* | Nonsense Mutation (SNP) | VAF 36/157 reads (23%) | catalogued as COSV63122877; called by muse, mutect2, varscan2
- F8 | c.2519C>T p.S840L | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV64272008; called by muse, mutect2, varscan2
- FAM131B | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 394/1019 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV58369083; called by muse, mutect2, varscan2
- FAM47A | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 107/143 reads (75%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs756452001, COSV60493630; called by muse, varscan2
- FAM47C | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 195/262 reads (74%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782794129, COSV100793054; called by muse, mutect2, varscan2
- FAM50A | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 371/495 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99341258; called by muse, varscan2
- FAM53A | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57401114; called by muse, mutect2
- FAM83B | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV60920165; called by muse, mutect2, varscan2
- FAN1 | c.2569G>A p.D857N | Missense Mutation (SNP) | VAF 316/888 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62950351; called by muse, varscan2
- FANCG | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 289/752 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV62720188; called by muse, mutect2, varscan2
- FAP | c.1959G>A p.W653* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as rs760260596, COSV99502657; called by muse, mutect2, varscan2
- FAT1 | c.10351G>A p.E3451K | Missense Mutation (SNP) | VAF 48/62 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747276580, COSV71673367; called by muse, mutect2, varscan2
- FAT2 | c.4643G>A p.G1548E | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.56); PolyPhen benign (0.054); catalogued as COSV55816941; called by muse, mutect2, varscan2
- FAT2 | c.4642G>A p.G1548R | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs747941533, COSV99944549; called by muse, mutect2, varscan2
- FAT4 | c.13180C>T p.P4394S | Missense Mutation (SNP) | VAF 128/694 reads (18%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.772); catalogued as rs772779154, COSV58679780; ClinVar: uncertain significance; called by muse, varscan2
- FBN1 | c.7895T>C p.M2632T | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV57314365; called by muse, mutect2, varscan2
- FBN3 | c.4565C>T p.S1522F | Missense Mutation (SNP) | VAF 91/306 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV54458263; called by muse, mutect2, varscan2
- FBXO2 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 198/612 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as COSV99279161; called by muse, mutect2, varscan2
- FBXO2 | c.570G>A p.W190* | Nonsense Mutation (SNP) | VAF 199/613 reads (32%) | catalogued as COSV99279163; called by muse, mutect2, varscan2
- FBXO7 | c.256A>G p.N86D | Missense Mutation (SNP) | VAF 457/1300 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as rs759929611, COSV56677338; called by muse, mutect2, varscan2
- FBXW7 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 19/25 reads (76%) | catalogued as COSV55898137; called by muse, mutect2, varscan2
- FCER2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 158/431 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.721); catalogued as COSV60916184; called by muse, mutect2, varscan2
- FCRL4 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs1558152778, COSV99620674; called by muse, mutect2, varscan2
- FDPS | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 219/797 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.4); catalogued as COSV63114301; called by muse, mutect2, varscan2
- FER1L6 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as COSV67549334; called by muse, mutect2, varscan2
- FGFR2 | c.2122C>T p.P708S | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60644612; called by muse, varscan2
- FGFR2 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 169/562 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60644655; called by muse, mutect2, varscan2
- FHDC1 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 267/344 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs374152732; called by muse, mutect2, varscan2
- FKBP3 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV53531844; called by muse, mutect2, varscan2
- FLT4 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 207/432 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV56104972; called by muse, mutect2, varscan2
- FOLH1 | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 24/152 reads (16%) | catalogued as rs372239425, COSV57048008; called by muse, mutect2, varscan2
- FOLH1 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408007611, COSV57048018; called by muse, mutect2, varscan2
- FOXD4L4 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 393/1413 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); catalogued as rs1428587926; called by muse, mutect2, varscan2
- FOXO1 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 157/344 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as rs199932286, COSV65426257; called by muse, mutect2, varscan2
- FOXP4 | c.1753C>A p.L585I (on ENST00000307972 / NM_001012426.1; = p.L572I on NM_138457.3) | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV100333124; called by muse, mutect2, varscan2
- FPR1 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as COSV59051672; called by muse, mutect2
- FREM2 | c.8869C>T p.Q2957* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV54834660; called by muse, mutect2, varscan2
- FSCN3 | c.407G>A p.W136* | Nonsense Mutation (SNP) | VAF 150/379 reads (40%) | catalogued as COSV50000770; called by muse, mutect2, varscan2
- FSIP2 | c.16628C>T p.T5543I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV58083299; called by mutect2, varscan2
- FYB1 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.137); catalogued as rs1182510705, COSV60944653; called by muse, mutect2, varscan2
- FYB2 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV58584329, COSV58587681; called by muse, mutect2, varscan2
- FYCO1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 198/534 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV56115287; called by muse, mutect2, varscan2
- G6PC | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs534670926, COSV53830677; called by muse, mutect2, varscan2
- GABRE | c.1476C>A p.F492L | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64819350; called by muse, mutect2, varscan2
- GADL1 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99245295; called by muse, mutect2, varscan2
- GALM | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV55371227; called by muse, mutect2, varscan2
- GALNT13 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.925); catalogued as COSV67217136; called by muse, mutect2, varscan2
- GALNT13 | c.1393C>T p.Q465* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV67211283; called by muse, mutect2, varscan2
- GATA1 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 62/78 reads (79%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.346); catalogued as COSV64962002; called by muse, mutect2, varscan2
- GBP1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 113/334 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV65083243; called by muse, mutect2, varscan2
- GCFC2 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 224/573 reads (39%) | catalogued as rs774236115, COSV58080581; called by muse, mutect2, varscan2
- GCFC2 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 221/598 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV58080594; called by muse, mutect2, varscan2
- GIMAP7 | c.372G>A p.M124I | Missense Mutation (SNP) | VAF 154/413 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as COSV57958942; called by muse, mutect2, varscan2
- GIMAP8 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.621); catalogued as COSV56230281; called by muse, mutect2, varscan2
- GLI2 | c.4571C>T p.S1524F (on ENST00000361492 / NM_001374353.1; = p.S1541F on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 504/1415 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM055284, COSV58039463, COSV58053907; called by muse, mutect2, varscan2
- GOLM2 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 148/400 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs374320339; called by muse, mutect2, varscan2
- GPCPD1 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.068); catalogued as COSV66830560; called by muse, mutect2, varscan2
- GPR156 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV59939172; called by muse, mutect2, varscan2
- GPR158 | c.2792C>T p.S931F | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV66266808; called by muse, mutect2, varscan2
- GPR55 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 95/262 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as rs774169195, COSV67407495; called by muse, mutect2, varscan2
- GPR87 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.019); catalogued as rs369844880; called by muse, mutect2, varscan2
- GRAMD1A | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 487/1328 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58766678; called by muse, mutect2, varscan2
- GRAMD1B | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.893); catalogued as rs537927876, COSV59202875; called by muse, mutect2, varscan2
- GRHL1 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 203/549 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs766376962, COSV61407527; called by muse, mutect2, varscan2
- GRID1 | c.2980G>A p.G994R | Missense Mutation (SNP) | VAF 106/267 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV60023704; called by muse, mutect2, varscan2
- GRIN2A | c.3943G>A p.D1315N | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs759696882, COSV58028750; called by muse, mutect2, varscan2
- GRK4 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV61668682; called by muse, mutect2
- GSE1 | c.1313-1G>A p.X438_splice | Splice Site (SNP) | VAF 197/573 reads (34%) | catalogued as COSV53671222; called by muse, mutect2, varscan2
- GTF2F1 | c.133-1G>A p.X45_splice | Splice Site (SNP) | VAF 387/973 reads (40%) | catalogued as COSV66725498; called by muse, mutect2, varscan2
- GTF2F2 | c.598A>C p.K200Q | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV61239036; called by muse, mutect2
- GTPBP10 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99746401; called by muse, mutect2, varscan2
- GTPBP10 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55986522, COSV99746404; called by muse, mutect2, varscan2
- GUCY1A1 | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56650911; called by muse, mutect2, varscan2
- GUCY2C | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV53789079, COSV53792540; called by muse, mutect2, varscan2
- GUCY2D | c.1459G>A p.V487M | Missense Mutation (SNP) | VAF 393/631 reads (62%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV54695739; called by muse, mutect2, varscan2
- GZMA | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57112489; called by muse, mutect2, varscan2
- GZMM | c.601G>C p.A201P | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV52742071; called by muse, mutect2, varscan2
- H1-7 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 134/308 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1398389521, COSV58601839; called by muse, mutect2, varscan2
- HADHB | c.70A>T p.R24* | Nonsense Mutation (SNP) | VAF 83/291 reads (29%) | catalogued as COSV100502219; called by muse, mutect2, varscan2
- HADHB | c.71G>A p.R24K | Missense Mutation (SNP) | VAF 82/287 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100502223; called by muse, mutect2, varscan2
- HAO1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs866463468, COSV66491681; called by muse, mutect2, varscan2
- HBP1 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56017410; called by muse, varscan2
- HCRTR2 | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV63795136; called by muse, mutect2, varscan2
- HCRTR2 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.028); catalogued as rs199706844, COSV100904284, COSV63794581; called by mutect2, varscan2
- HDAC3 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 241/356 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59495592; called by muse, mutect2, varscan2
- HDAC7 | c.367G>A p.E123K (on ENST00000427332; = p.E162K on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 274/578 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.109); catalogued as COSV50338415; called by muse, mutect2, varscan2
- HDC | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 138/353 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs769839707, COSV51068917; called by muse, mutect2, varscan2
- HDGFL3 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV55205473; called by muse, varscan2
- HEATR3 | c.994C>A p.H332N | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV53528864; called by muse, varscan2
- HECW2 | c.46A>G p.N16D | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.054); catalogued as COSV53656134; called by muse, varscan2
- HERC1 | c.3607G>A p.G1203R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV71247191; called by muse, mutect2, varscan2
- HGD | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV52199543; called by muse, mutect2, varscan2
- HGD | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV99381550; called by muse, mutect2, varscan2
- HHIP | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 114/667 reads (17%) | catalogued as COSV56838640; called by muse, mutect2, varscan2
- HIC2 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 224/621 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68041978; called by muse, mutect2, varscan2
- HMBOX1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs763363239, COSV55067536; called by muse, mutect2, varscan2
- HMCN1 | c.8846C>T p.A2949V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54892601; called by muse, mutect2, varscan2
- HMCN1 | c.13847C>T p.P4616L | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54892614; called by muse, mutect2, varscan2
- HMGCS2 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 200/506 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.14); catalogued as rs144103604; ClinVar: uncertain significance; called by muse, varscan2
- HMGXB4 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 155/362 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.828); catalogued as COSV53333551; called by muse, mutect2, varscan2
- HNRNPAB | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 225/350 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV57423670; called by muse, mutect2, varscan2
- HOOK1 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.893); catalogued as rs764797480, COSV100969299; called by muse, mutect2, varscan2
- HOXA2 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 417/1084 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as COSV56065823; called by muse, mutect2, varscan2
- HOXB6 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 660/1893 reads (35%) | catalogued as COSV99494814; called by muse, mutect2, varscan2
- HPSE | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 70/138 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV60986395; called by muse, mutect2, varscan2
- HRNR | c.2290G>A p.G764S | Missense Mutation (SNP) | VAF 486/862 reads (56%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as rs750750547, COSV64256732; called by muse, mutect2, varscan2
- HSPA12B | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 509/1430 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV54766342; called by muse, mutect2, varscan2
- HSPG2 | c.2663C>T p.S888F | Missense Mutation (SNP) | VAF 108/322 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV65970723; called by muse, mutect2, varscan2
- HTR1D | c.140T>A p.V47D | Missense Mutation (SNP) | VAF 168/485 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV100025115; called by muse, mutect2, varscan2
- HTR1D | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 170/486 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs780246153, COSV100025116; called by muse, mutect2, varscan2
- HTR2C | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.011); catalogued as COSV52207433; called by muse, mutect2, varscan2
- HTR5A | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 152/419 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55282232; called by muse, mutect2, varscan2
- HTRA1 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 351/972 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.13); catalogued as rs751200867, COSV64563953; called by muse, mutect2, varscan2
- HYDIN | c.7201G>A p.E2401K | Missense Mutation (SNP) | VAF 150/528 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as rs772680657, COSV59250071; called by muse, mutect2, varscan2
- ICE2 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 97/220 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV55030712; called by muse, mutect2, varscan2
- IER5 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1315571684, COSV62537025; called by muse, mutect2
- IFNA2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 143/374 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV66505492; called by muse, mutect2, varscan2
- IFNA4 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.052); catalogued as COSV70179801; called by muse, varscan2
- IFT74 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 133/358 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV66286530; called by muse, mutect2, varscan2
- IGFBPL1 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 156/501 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1342310498, COSV66617990; called by muse, mutect2, varscan2
- IGHG4 | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 596/2638 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs112825195; called by muse, mutect2, varscan2
- IGHV3-20 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.842); catalogued as rs370384431; called by muse, mutect2, varscan2
- IGKV2-28 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs1466386564; called by mutect2, varscan2
- IGSF1 | c.3487C>T p.P1163S | Missense Mutation (SNP) | VAF 211/283 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63836947; called by muse, mutect2, varscan2
- IKZF1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV58783378, COSV58790054; called by muse, mutect2, varscan2
- IL17RA | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 146/403 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60052558; called by muse, mutect2, varscan2
- IL1R1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52104786; called by muse, mutect2, varscan2
- IL7 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55674093; called by muse, mutect2, varscan2
- ILDR1 | c.1615C>T p.H539Y (on ENST00000344209 / NM_001199799.2; = p.H495Y on NM_175924.4) | Missense Mutation (SNP) | VAF 114/273 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV56549487; called by muse, mutect2, varscan2
- INPPL1 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 276/1218 reads (23%) | catalogued as COSV53354789; called by muse, mutect2, varscan2
- INSRR | c.2217G>A p.R739= | Splice Region (SNP) | VAF 183/328 reads (56%) | catalogued as rs755164242, COSV63872282; called by muse, mutect2, varscan2
- IPO7 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65684712, COSV65684801; called by muse, mutect2, varscan2
- IQSEC1 | c.347T>G p.L116R | Missense Mutation (SNP) | VAF 87/184 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56223147; called by muse, mutect2, varscan2
- IRAG1 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV70210645, COSV70212459; called by muse, mutect2, varscan2
- IRAK2 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 424/1080 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV56529218; called by muse, mutect2, varscan2
- IRGC | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 237/654 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.117); catalogued as rs1207095890, COSV54983753; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 175/458 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV59348930; called by muse, mutect2, varscan2
- ITGA5 | c.2260C>T p.L754F | Missense Mutation (SNP) | VAF 126/270 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV53217049; called by muse, mutect2, varscan2
- ITGA5 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 252/491 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as rs776870697, COSV53217061; called by muse, mutect2, varscan2
- ITGB2 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 394/609 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV56609496; called by muse, mutect2, varscan2
- ITLN2 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 74/320 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.738); catalogued as COSV63537632; called by muse, mutect2, varscan2
- JAKMIP2 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 228/400 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54601908; called by muse, mutect2, varscan2
- KANK3 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 291/824 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.395); catalogued as COSV100035535, COSV56846324; called by muse, mutect2, varscan2
- KAZN | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 330/809 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63207630; called by muse, mutect2, varscan2
- KCNC2 | c.1237C>A p.P413T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.973); catalogued as COSV54366999; called by muse, mutect2, varscan2
- KCND2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 202/571 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV58576373; called by muse, mutect2, varscan2
- KCNH6 | c.1955G>A p.G652E | Missense Mutation (SNP) | VAF 195/578 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as COSV59002581; called by muse, mutect2, varscan2
- KCNH7 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59787670; called by muse, mutect2, varscan2
- KCNH7 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 111/308 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59793690; called by muse, mutect2, varscan2
- KCNJ3 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 133/375 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54534807, COSV54546456; called by muse, mutect2, varscan2
- KCNQ2 | c.1849C>T p.P617S (on ENST00000359125 / NM_172107.4; = p.P589S on NM_004518.6) | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as rs776037713, COSV100610696; called by muse, varscan2
- KCNQ5 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs148819747, COSV59656719; called by muse, mutect2, varscan2
- KDF1 | c.1040-1G>A p.X347_splice | Splice Site (SNP) | VAF 263/697 reads (38%) | catalogued as COSV57671038; called by muse, mutect2, varscan2
- KDM3B | c.2860C>T p.R954C | Missense Mutation (SNP) | VAF 84/131 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs866179776, COSV58689822; called by muse, mutect2, varscan2
- KDM4A | c.1755T>A p.F585L | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV64959264, COSV64960060; called by muse, mutect2, varscan2
- KDM4D | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV58634333; called by muse, mutect2, varscan2
- KDM5A | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as rs779919288, COSV66991368; called by muse, mutect2, varscan2
- KDM5B | c.3922C>T p.P1308S | Missense Mutation (SNP) | VAF 95/309 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV52506805; called by muse, mutect2, varscan2
- KHDRBS2 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140624162, COSV55443814; called by muse, varscan2
- KIAA1210 | c.5102G>A p.W1701* | Nonsense Mutation (SNP) | VAF 338/432 reads (78%) | catalogued as COSV68176633; called by muse, mutect2, varscan2
- KIAA1549 | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as rs780555852, COSV54311297; called by muse, mutect2, varscan2
- KIAA1549 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 95/291 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV54311326; called by muse, mutect2, varscan2
- KIAA1549L | c.4616C>T p.S1539F (on ENST00000321505; = p.S1836F on NM_012194.3) | Missense Mutation (SNP) | VAF 152/746 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58586090; called by muse, mutect2
- KIDINS220 | c.3898C>T p.P1300S | Missense Mutation (SNP) | VAF 152/410 reads (37%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV56752334; called by muse, mutect2, varscan2
- KIF1A | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 180/548 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100242810; called by muse, mutect2, varscan2
- KIF2B | c.1969A>G p.K657E | Missense Mutation (SNP) | VAF 107/302 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV52129360; called by muse, mutect2, varscan2
- KIR2DL1 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 232/946 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs200492424, COSV52415077; called by muse, varscan2
- KIR2DL4 | c.907C>T p.R303C (on ENST00000396284; = p.R264C on NM_001080772.2) | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs748541591, COSV58497181; called by muse, mutect2, varscan2
- KLHL20 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 113/192 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV52941328; called by muse, mutect2, varscan2
- KLK5 | c.32T>G p.V11G | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV60450002; called by muse, varscan2
- KMT2A | c.6674C>T p.S2225F | Missense Mutation (SNP) | VAF 79/156 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV63284562; called by muse, mutect2, varscan2
- KMT2B | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 105/255 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV55859754; called by muse, mutect2, varscan2
- KMT2C | c.11080C>T p.P3694S | Missense Mutation (SNP) | VAF 435/1141 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV51428743; called by muse, mutect2, varscan2
- KMT2D | c.14731C>T p.P4911S | Missense Mutation (SNP) | VAF 257/1032 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.702); catalogued as COSV56428890; called by muse, mutect2, varscan2
- KMT2D | c.8573C>T p.S2858F | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs1439459361, COSV56428903; called by muse, mutect2
- KNSTRN | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 292/703 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); catalogued as COSV51104494; called by muse, mutect2, varscan2
- KPNA3 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 140/335 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV55504258; called by muse, mutect2, varscan2
- KRBA2 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 387/594 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as COSV58778948; called by muse, mutect2, varscan2
- KRT15 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 215/551 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as rs753481169, COSV54178716; called by muse, mutect2, varscan2
- KRT4 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 66/404 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV53406492; called by muse, mutect2, varscan2
- KRT71 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 284/656 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV57289768; called by muse, mutect2, varscan2
- KRTAP10-6 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 438/722 reads (61%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs782668686, COSV59958399; called by muse, varscan2
- KRTAP4-1 | c.415C>T p.P139S (on ENST00000398472; = p.P120S on NM_033060.3) | Missense Mutation (SNP) | VAF 550/1497 reads (37%) | SIFT tolerated (0.06); catalogued as rs1444047761, COSV66648178; called by muse, mutect2, varscan2
- KRTAP5-3 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 269/1279 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV101294500, COSV68790649; called by muse, mutect2, varscan2
- KTN1 | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV68023165; called by muse, mutect2, varscan2
- LACTB2 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52567513; called by muse, mutect2, varscan2
- LACTB2 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 134/370 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52567525; called by muse, mutect2, varscan2
- LAMB3 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 423/838 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV61916353; called by muse, mutect2, varscan2
- LAMB3 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 179/685 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as rs549692468, CD031511, COSV61916357; called by muse, mutect2, varscan2
- LAMP5 | c.473G>C p.S158T | Missense Mutation (SNP) | VAF 210/569 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV55715811; called by muse, mutect2, varscan2
- LCE5A | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 295/512 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); catalogued as COSV57500275, COSV57500704; called by muse, mutect2, varscan2
- LCOR | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 57/188 reads (30%) | catalogued as COSV63630703; called by muse, mutect2, varscan2
- LCP1 | c.1626G>A p.K542= | Splice Region (SNP) | VAF 31/55 reads (56%) | catalogued as COSV100549996, COSV59940505; called by muse, mutect2, varscan2
- LCP2 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs550283765, COSV50448758; called by muse, varscan2
- LGMN | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 450/1216 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58403334; called by muse, mutect2, varscan2
- LHFPL5 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 644/1689 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as COSV64177552; called by muse, mutect2, varscan2
- LIG1 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 182/510 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs111507847, COSV54390877; called by muse, mutect2, varscan2
- LILRA4 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 183/472 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV52491499; called by muse, mutect2, varscan2
- LILRB5 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 279/815 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV60256554; called by muse, mutect2, varscan2
- LMO7 | c.1582G>A p.D528N (on ENST00000357063; = p.D258N on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); catalogued as COSV58533676; called by muse, mutect2, varscan2
- LMO7 | c.1649A>C p.E550A (on ENST00000357063; = p.E280A on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58533691; called by muse, mutect2, varscan2
- LMO7 | c.4372G>T p.E1458* (on ENST00000357063; = p.E1139* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 19/74 reads (26%) | catalogued as COSV58533707; called by muse, mutect2, varscan2
- LMTK2 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 159/469 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.839); catalogued as COSV51991477; called by muse, mutect2, varscan2
- LMX1A | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54219381; called by muse, mutect2, varscan2
- LPA | c.4333C>T p.R1445C | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs778266525, COSV60300378; called by muse, mutect2, varscan2
- LPA | c.3149G>A p.G1050E | Missense Mutation (SNP) | VAF 36/47 reads (77%) | SIFT tolerated (0.21); PolyPhen benign (0.157); catalogued as COSV60300384; called by muse, mutect2, varscan2
- LPIN1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 460/1244 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV56764470; called by muse, mutect2, varscan2
- LPIN1 | c.1025T>A p.F342Y | Missense Mutation (SNP) | VAF 277/626 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV56764484; called by muse, mutect2, varscan2
- LRIG2 | c.2758C>T p.P920S | Missense Mutation (SNP) | VAF 165/410 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV63161638; called by muse, mutect2, varscan2
- LRP1 | c.886T>G p.F296V | Missense Mutation (SNP) | VAF 157/738 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV54507945; called by muse, mutect2, varscan2
- LRP1 | c.11663C>T p.S3888L | Missense Mutation (SNP) | VAF 210/415 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.06); catalogued as rs745620359, COSV54507955; called by muse, mutect2, varscan2
- LRP1B | c.10769-1G>A p.X3590_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | catalogued as COSV67206500; called by mutect2, varscan2
- LRRC17 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV50864460; called by muse, mutect2, varscan2
- LRRC34 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV57185957; called by muse, mutect2, varscan2
- LRRC43 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 73/303 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60289389; called by muse, mutect2, varscan2
- LRRC66 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV58633093; called by muse, mutect2, varscan2
- LRRCC1 | c.1502A>G p.K501R | Missense Mutation (SNP) | VAF 201/579 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV64483177; called by muse, mutect2, varscan2
- LRRIQ1 | c.4000G>A p.E1334K | Missense Mutation (SNP) | VAF 136/315 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV67829144, COSV67839568; called by muse, mutect2, varscan2
- LRTM1 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV55530079; called by muse, mutect2, varscan2
- LUZP2 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV61201528; called by muse, mutect2, varscan2
- LYST | c.1535A>G p.H512R | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759547330, COSV67706018; called by muse, varscan2
- M1AP | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV51843922; called by muse, mutect2, varscan2
- MAGEC1 | c.3383A>T p.E1128V | Missense Mutation (SNP) | VAF 67/83 reads (81%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.063); catalogued as COSV53571132; called by muse, mutect2, varscan2
- MAGEC2 | c.25T>A p.F9I | Missense Mutation (SNP) | VAF 260/369 reads (70%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.019); catalogued as COSV55998898; called by muse, mutect2, varscan2
- MAGI1 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58322157; called by muse, mutect2, varscan2
- MAGI2 | c.1295G>A p.S432N | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV62646882, COSV62671388; called by muse, mutect2, varscan2
- MAGI2 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62646897; called by muse, mutect2, varscan2
- MANEAL | c.799T>G p.F267V (on ENST00000373045 / NM_001113482.1; = p.F45V on NM_152496.2) | Missense Mutation (SNP) | VAF 619/1577 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV61115907; called by muse, mutect2, varscan2
- MAP1S | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 106/324 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV60722316; called by muse, mutect2, varscan2
- MAP3K11 | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1182749295, COSV100442415; called by muse, mutect2, varscan2
- MAP3K21 | c.1882C>T p.Q628* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as COSV64041483; called by muse, mutect2, varscan2
- MAP3K5 | c.3021A>T p.E1007D | Missense Mutation (SNP) | VAF 140/200 reads (70%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.97); catalogued as COSV62888657; called by muse, varscan2
- MAPK3 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 399/915 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs747392494, COSV53771821, COSV53772684; called by muse, mutect2, varscan2
- MAPK6 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs367920269, COSV55929260; called by muse, mutect2, varscan2
- MARCHF2 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 223/639 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53104700; called by muse, mutect2, varscan2
- MARCO | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59053635; called by muse, mutect2, varscan2
- MARK3 | c.1514G>C p.R505P | Missense Mutation (SNP) | VAF 89/335 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53509209, COSV99358778; called by muse, mutect2, varscan2
- MBNL1 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56826999; called by muse, mutect2, varscan2
- MBNL2 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 212/613 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV59119916; called by muse, mutect2, varscan2
- MCCC1 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 171/416 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV55608067; called by muse, mutect2, varscan2
- MCF2L | c.319C>T p.P107S (on ENST00000375608; = p.P75S on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 270/746 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.377); catalogued as COSV65050124; called by muse, mutect2, varscan2
- MCM2 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 204/520 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.744); catalogued as COSV54033144; called by muse, mutect2, varscan2
- MEGF10 | c.2905A>C p.K969Q | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as COSV57247977, COSV57248362; called by muse, mutect2, varscan2
- MEGF6 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV99621644; called by muse, mutect2, varscan2
- MEP1B | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 99/315 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52496918; called by muse, varscan2
- MEP1B | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV52496930; called by muse, mutect2, varscan2
- MERTK | c.644A>G p.N215S | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.883); catalogued as COSV54927595; called by muse, mutect2, varscan2
- METTL2B | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 128/350 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52308505; called by muse, mutect2, varscan2
- MFSD1 | c.50A>T p.D17V | Missense Mutation (SNP) | VAF 105/277 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV51840159; called by muse, mutect2, varscan2
- MGAM | c.4042G>A p.D1348N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV72074435; called by muse, mutect2
- MGAT3 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 158/394 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57864961; called by muse, varscan2
- MICAL3 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 302/761 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV52895421; called by muse, mutect2, varscan2
- MIOX | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs1247805887, COSV53312591; called by muse, mutect2, varscan2
- MLLT6 | c.2012C>T p.S671F | Missense Mutation (SNP) | VAF 147/399 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs770302162; called by muse, mutect2, varscan2
- MMP10 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1328664790, COSV54246032; called by muse, mutect2, varscan2
- MN1 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 347/928 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs951572274, COSV56557628; called by muse, mutect2, varscan2
- MOG | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 45/137 reads (33%) | catalogued as rs767614040, COSV65320989; called by muse, mutect2, varscan2
- MPP2 | c.1610G>A p.G537E (on ENST00000461854 / NM_001278372.2; = p.G513E on NM_005374.5) | Missense Mutation (SNP) | VAF 143/437 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.062); catalogued as rs1173152682, COSV99290966; called by muse, mutect2, varscan2
- MPP2 | c.1609G>A p.G537R (on ENST00000461854 / NM_001278372.2; = p.G513R on NM_005374.5) | Missense Mutation (SNP) | VAF 142/436 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as COSV52235443; called by muse, mutect2, varscan2
- MPP6 | c.824C>A p.P275Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56037338; called by muse, mutect2, varscan2
- MRNIP | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 252/407 reads (62%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as COSV99481880; called by muse, mutect2, varscan2
- MROH7 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as COSV59870698; called by muse, mutect2, varscan2
- MROH7 | c.3680C>T p.P1227L | Missense Mutation (SNP) | VAF 252/672 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs868046332, COSV64886568, COSV64886917; called by muse, mutect2, varscan2
- MSTN | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV53620776; called by muse, mutect2, varscan2
- MTTP | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1415163762, COSV55505190; called by muse, mutect2, varscan2
- MUC16 | c.32174C>T p.P10725L | Missense Mutation (SNP) | VAF 109/319 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); catalogued as COSV67450083, COSV67459342; called by muse, mutect2, varscan2
- MUC16 | c.25181C>T p.S8394F | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV67459360; called by muse, mutect2, varscan2
- MUC16 | c.22178C>T p.S7393F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV67459374; called by muse, mutect2, varscan2
- MUC16 | c.20944G>A p.E6982K | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV67459385; called by muse, mutect2, varscan2
- MUC16 | c.16562G>A p.R5521K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.065); catalogued as COSV67459396; called by muse, mutect2, varscan2
- MUC16 | c.12923G>T p.G4308V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV67459413; called by muse, mutect2, varscan2
- MUC16 | c.12452C>T p.P4151L | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.262); catalogued as rs375469297; called by muse, mutect2, varscan2
- MUC16 | c.6340C>T p.Q2114* | Nonsense Mutation (SNP) | VAF 72/199 reads (36%) | catalogued as COSV67446155, COSV67459437; called by muse, mutect2, varscan2
- MUC17 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 392/1114 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV60285703; called by muse, mutect2, varscan2
- MXRA5 | c.4825C>T p.P1609S | Missense Mutation (SNP) | VAF 444/580 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1463757120, COSV54231696; called by muse, mutect2, varscan2
- MYBL1 | c.201T>A p.N67K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.421); catalogued as COSV72918906; called by muse, mutect2, varscan2
- MYCBP2 | c.6826T>A p.S2276T (on ENST00000357337; = p.S2314T on NM_015057.5) | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as COSV62015291; called by muse, mutect2, varscan2
- MYCT1 | c.190T>A p.F64I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100924103, COSV65891763; called by muse, mutect2, varscan2
- MYH1 | c.3258G>A p.K1086= | Splice Region (SNP) | VAF 74/108 reads (69%) | catalogued as COSV56846634; called by muse, mutect2, varscan2
- MYH11 | c.4444G>A p.E1482K | Missense Mutation (SNP) | VAF 227/619 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV55546598; called by muse, mutect2, varscan2
- MYH11 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 148/448 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55549522; called by muse, mutect2, varscan2
- MYH15 | c.5148A>C p.E1716D | Missense Mutation (SNP) | VAF 84/221 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV56308099; called by muse, mutect2, varscan2
- MYH15 | c.1810G>A p.G604S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV56308110; called by muse, mutect2, varscan2
- MYH7 | c.4085C>T p.S1362F | Missense Mutation (SNP) | VAF 282/681 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1335436245, COSV62518259; called by muse, mutect2, varscan2
- MYLK | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 117/360 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60608109; called by muse, mutect2, varscan2
- MYO16 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 122/309 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51787855; called by muse, mutect2, varscan2
- MYO18B | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 79/186 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59131252; called by muse, mutect2, varscan2
- MYO1H | c.2707A>T p.K903* | Nonsense Mutation (SNP) | VAF 41/156 reads (26%) | catalogued as COSV60444683; called by muse, mutect2, varscan2
- MYO5B | c.2684G>C p.R895P | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53216168, COSV99545631; called by muse, mutect2, varscan2
- MYO7B | c.2791G>A p.G931S | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV67346701; called by muse, mutect2, varscan2
- MYO7B | c.3964G>A p.E1322K | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as rs757581563, COSV67346716; called by muse, mutect2, varscan2
- MYOCD | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 138/272 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV58501665; called by muse, mutect2, varscan2
- MYOCD | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58497540; called by muse, mutect2, varscan2
- MYOM1 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.904); catalogued as rs866361705, COSV55289625; called by muse, mutect2, varscan2
- MYOM1 | c.97A>C p.K33Q | Missense Mutation (SNP) | VAF 172/500 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as rs888704455, COSV55289636; called by muse, mutect2
- MYT1L | c.89G>A p.S30N | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV67717240; called by muse, mutect2, varscan2
- NAALADL1 | c.2213C>T p.A738V | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV57246533; called by muse, mutect2, varscan2
- NALCN | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51929263; called by mutect2, varscan2
- NBAS | c.6783G>T p.E2261D | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as COSV55718420; called by muse, mutect2, varscan2
- NBEA | c.4945C>T p.P1649S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as COSV59776629; called by mutect2, varscan2
- NBEA | c.8309C>T p.P2770L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1450566339, COSV59776636; called by muse, mutect2, varscan2
- NBEA | c.8413C>T p.L2805F | Missense Mutation (SNP) | VAF 99/308 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs1194427538, COSV100085227; called by muse, mutect2, varscan2
- NBPF3 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 203/725 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV59058295; called by muse, mutect2, varscan2
- NCKAP1L | c.363C>T p.I121= | Splice Region (SNP) | VAF 26/143 reads (18%) | catalogued as rs199795735; called by muse, mutect2, varscan2
- NCKAP5L | c.1954C>G p.R652G | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as COSV60128874, COSV60129351; called by muse, mutect2
- NDC1 | c.1424C>G p.P475R | Missense Mutation (SNP) | VAF 99/229 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV52334595; called by muse, mutect2, varscan2
- NDST3 | c.2075C>T p.T692I | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.944); catalogued as COSV56616990; called by muse, mutect2, varscan2
- NEB | c.12541C>T p.R4181W | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs769673154, COSV99429300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NELFB | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 66/105 reads (63%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs376737086; called by muse, varscan2
- NELFB | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 68/109 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100547106; called by muse, mutect2, varscan2
- NEUROD4 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV54471232; called by muse, mutect2, varscan2
- NF1 | c.8023C>T p.P2675S (on ENST00000358273 / NM_001042492.3; = p.P2654S on NM_000267.3) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.039); catalogued as COSV62199827; called by muse, mutect2, varscan2
- NFX1 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59309551; called by muse, mutect2, varscan2
- NKX6-1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 239/1232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55684444; called by muse, varscan2
- NLRC4 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100707431, COSV61592212; called by muse, mutect2, varscan2
- NLRP10 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100149618, COSV60779895; called by muse, mutect2, varscan2
- NLRP11 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.127); catalogued as rs1017942789, COSV64086717; called by muse, mutect2, varscan2
- NLRP3 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 99/199 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV60221154; called by muse, mutect2, varscan2
- NLRP5 | c.1972C>T p.P658S | Missense Mutation (SNP) | VAF 207/576 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV66763700; called by muse, mutect2, varscan2
- NLRP9 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 111/332 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs759340206, COSV60461331; called by muse, mutect2, varscan2
- NME7 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63166293; called by muse, mutect2, varscan2
- NOC4L | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1354887216, COSV57957890; called by muse, mutect2, varscan2
- NOD1 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 304/749 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs1301364329, COSV56112010; called by muse, mutect2, varscan2
- NOD2 | c.3059G>A p.G1020E | Missense Mutation (SNP) | VAF 96/295 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56049684; called by muse, mutect2, varscan2
- NOL4 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 201/510 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV52338537; called by muse, varscan2
- NOL4 | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 200/516 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99309006; called by muse, varscan2
- NOS1 | c.3271C>A p.P1091T | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100501169, COSV57610437; called by muse, mutect2, varscan2
- NOS1 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57610370; called by muse, mutect2, varscan2
- NOS1 | c.2368G>A p.V790M | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV57610452; called by muse, mutect2, varscan2
- NPBWR2 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 107/294 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs748271416, COSV63899953; called by muse, mutect2, varscan2
- NPHS1 | c.2635G>A p.G879R | Missense Mutation (SNP) | VAF 97/241 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201505524, CM044683, COSV62287352; called by muse, mutect2, varscan2
- NR5A1 | c.993G>A p.V331= | Splice Region (SNP) | VAF 172/252 reads (68%) | catalogued as COSV65294828; called by muse, mutect2, varscan2
- NREP | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); catalogued as COSV57405016; called by mutect2, varscan2
- NRN1 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV55205360; called by muse, mutect2, varscan2
- NRXN1 | c.3221G>A p.G1074E | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58446227, COSV58451619; called by muse, mutect2, varscan2
- NSMAF | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50685694; called by muse, mutect2, varscan2
- NTN5 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.949); catalogued as rs745982299, COSV54306929; called by muse, mutect2
- NUMA1 | c.6152G>A p.S2051N | Missense Mutation (SNP) | VAF 479/1032 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV52620458; called by muse, mutect2, varscan2
- NUP210 | c.5657C>T p.S1886F | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV54405057; called by muse, mutect2, varscan2
- NWD1 | c.3001G>A p.D1001N | Missense Mutation (SNP) | VAF 101/339 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV100344006; called by muse, mutect2, varscan2
- NWD1 | c.3002A>T p.D1001V | Missense Mutation (SNP) | VAF 104/336 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV100344009; called by muse, mutect2, varscan2
- NWD1 | c.3221C>T p.S1074F | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.372); catalogued as COSV60340808; called by muse, mutect2, varscan2
- NYAP2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 200/594 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1429976399, COSV56003008, COSV56006040; called by muse, mutect2, varscan2
- OASL | c.428G>A p.R143K | Missense Mutation (SNP) | VAF 222/1011 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV99984696; called by muse, mutect2, varscan2
- OBSCN | c.5042G>A p.R1681Q | Missense Mutation (SNP) | VAF 405/750 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs924370909, COSV52763044; called by muse, mutect2, varscan2
- OGDH | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 94/261 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56048218; called by muse, mutect2, varscan2
- OPRPN | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 82/456 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); catalogued as COSV68192778; called by muse, mutect2, varscan2
- OR10A7 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs1340421753, COSV58278156; called by muse, mutect2, varscan2
- OR10G2 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 97/304 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1170305268, COSV73390352; called by muse, mutect2, varscan2
- OR10G7 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100390129; called by mutect2, varscan2
- OR10P1 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 80/416 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs752834026, COSV59007072; called by muse, mutect2, varscan2
- OR10Z1 | c.788A>T p.K263I | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV63524452; called by muse, varscan2
- OR10Z1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63524458; called by muse, varscan2
- OR13A1 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65572222; called by muse, mutect2, varscan2
- OR1I1 | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.003); catalogued as rs555736190, COSV99264956; called by muse, mutect2, varscan2
- OR2A2 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as rs765579556, COSV68871138; called by muse, varscan2
- OR2G6 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 99/202 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58573950; called by muse, mutect2, varscan2
- OR2L13 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 52/270 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV63551702; called by muse, mutect2, varscan2
- OR2W1 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV65851520; called by muse, mutect2, varscan2
- OR2Y1 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV57136439; called by muse, mutect2, varscan2
- OR4A15 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as rs149233751, COSV59033784, COSV59035376; called by muse, mutect2, varscan2
- OR4A47 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV71444895; called by mutect2, varscan2
- OR4B1 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 95/216 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV58882555; called by muse, mutect2, varscan2
- OR4C15 | c.442G>A p.E148K (on ENST00000314644; = p.E94K on NM_001001920.2) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.011); catalogued as COSV58952202; called by muse, mutect2, varscan2
- OR4K2 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 236/1882 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.085); catalogued as rs866350693, COSV53848275; called by muse, varscan2
- OR4K5 | c.588A>T p.E196D | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV60003112, COSV60005235; called by muse, mutect2, varscan2
- OR4M1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 92/445 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1026975289, COSV60060497, COSV60061265; called by muse, mutect2, varscan2
- OR4Q3 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV59178170; called by mutect2, varscan2
- OR51A2 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66748142; called by muse, mutect2, varscan2
- OR51B2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as COSV60915972; called by mutect2, varscan2
- OR51B2 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV60915845; called by muse, mutect2, varscan2
- OR51B5 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56175631; called by muse, varscan2
- OR51D1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs892712201, COSV62914074; called by muse, mutect2, varscan2
- OR51Q1 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 243/404 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56178510; called by muse, mutect2, varscan2
- OR52A1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs753102211, COSV61092141, COSV61093171; called by muse, mutect2, varscan2
- OR52K1 | c.192T>G p.F64L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100297764; called by muse, mutect2, varscan2
- OR52L1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 87/362 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs867894367, COSV59985811; called by muse, mutect2, varscan2
- OR56A3 | c.805A>G p.K269E | Missense Mutation (SNP) | VAF 114/568 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.033); catalogued as COSV61568898; called by muse, mutect2, varscan2
- OR5A2 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57390792; called by muse, mutect2
- OR5B17 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs1565142203, COSV100641982; called by mutect2, varscan2
- OR5F1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53546084; called by muse, mutect2, varscan2
- OR5K1 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV60303968; called by muse, mutect2, varscan2
- OR5K4 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV61583630; called by muse, mutect2, varscan2
- OR5K4 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759696555, COSV61583634, COSV61583906; called by muse, mutect2, varscan2
- OR5L1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61733527; called by muse, varscan2
- OR5P2 | c.941G>A p.S314N | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.02); catalogued as COSV61490323; called by muse, mutect2, varscan2
- OR5V1 | c.809A>T p.K270I | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.877); catalogued as COSV65827304; called by muse, mutect2, varscan2
- OR6K2 | c.806T>G p.L269W | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.957); catalogued as COSV62743355; called by muse, mutect2, varscan2
- OR8B2 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66664533; called by muse, mutect2, varscan2
- OR8H3 | c.70G>T p.V24F | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100539197, COSV57912419; called by muse, mutect2, varscan2
- OSMR | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as rs745947298, COSV57083904; called by muse, mutect2, varscan2
- OTOF | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99719433; called by muse, mutect2, varscan2
- OXCT1 | c.690C>A p.F230L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52169566; called by muse, mutect2, varscan2
1,055 further variants in this file (445 protein-altering or splice-affecting, 563 silent, 47 other) are not listed here.
